Somatic mutation profile of tumor specimen TCGA-32-2491-01A (aliquot TCGA-32-2491-01A-01D-1353-08) from TCGA case TCGA-32-2491, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.3 years (23,131 days).
Specimen TCGA-32-2491-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c0e5a26-431b-4de8-bf5d-2c3da58eb123.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-2491-10A (Blood Derived Normal), aliquot TCGA-32-2491-10A-01D-1353-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29ee4dcc-2384-4803-8b68-3d6c43721a72

The open-access MAF lists 64 somatic variants for this specimen: 50 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 11, Nonsense Mutation 2, Intron 1, 5'Flank 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3127A>G p.M1043V | Missense Mutation (SNP) | VAF 26/93 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1057519936, COSV55879858, COSV55890961; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1666C>T p.R556* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as rs121913304, CM942039, COSV57296489; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 44/109 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABL2 | c.1327G>A p.A443T (on ENST00000502732 / NM_007314.4; = p.A428T on NM_005158.5) | Missense Mutation (SNP) | VAF 66/251 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as COSV61012853; called by muse, mutect2, varscan2
- ACOX2 | c.1394C>T p.T465M | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.23); catalogued as rs1317973851, COSV57147955; called by muse, mutect2, varscan2
- CASZ1 | c.4156G>A p.A1386T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.09); catalogued as rs373145502; called by mutect2, varscan2
- CCDC87 | c.2386G>A p.E796K | Missense Mutation (SNP) | VAF 121/380 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs369370998; called by muse, mutect2, varscan2
- CDK6 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.177); catalogued as COSV56013614, COSV99720521; called by muse, mutect2
- CFAP20DC | c.1040C>T p.P347L (on ENST00000482387 / NM_001351530.2; = p.P222L on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.054); catalogued as rs141916956, COSV55920191; called by muse, varscan2
- COL1A2 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51958022; called by muse, mutect2, varscan2
- CP | c.2414T>A p.L805Q | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52830626; called by muse, mutect2, varscan2
- FAM170A | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs369994686; called by muse, mutect2, varscan2
- FAT3 | c.8863G>A p.D2955N | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs771847867, COSV53109882; called by muse, mutect2, varscan2
- FMO3 | c.633G>A p.M211I | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV63007237; called by muse, mutect2, varscan2
- FOXH1 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100023378; called by muse, mutect2
- FRAS1 | c.413A>G p.Q138R | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs747225163, COSV53610694; called by muse, mutect2, varscan2
- GRIN2C | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs185678892; called by muse, mutect2, varscan2
- HEPHL1 | c.3017A>G p.H1006R | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59891971; called by muse, mutect2, varscan2
- HSPG2 | c.8515G>C p.A2839P | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV65971584; called by muse, mutect2, varscan2
- MGAM | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 145/780 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs375055229, COSV72074642; called by muse, mutect2, varscan2
- MORC2 | c.848G>A p.R283H (on ENST00000397641 / NM_001303256.3; = p.R221H on NM_014941.3) | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1482880426, COSV53198733; called by muse, mutect2, varscan2
- MUC16 | c.31424C>T p.T10475I | Missense Mutation (SNP) | VAF 102/526 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV67465746; called by muse, mutect2, varscan2
- MUC17 | c.1256A>G p.D419G | Missense Mutation (SNP) | VAF 82/387 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs974339971, COSV60288461; called by muse, mutect2, varscan2
- MYO3B | c.3326A>G p.K1109R | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV58703144; called by muse, mutect2, varscan2
- NEK4 | c.1858C>T p.R620* | Nonsense Mutation (SNP) | VAF 74/291 reads (25%) | catalogued as rs775049834, COSV51780336; called by muse, mutect2, varscan2
- OR10H1 | c.121G>T p.G41C | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58471427; called by muse, mutect2, varscan2
- OR2G6 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 72/189 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs370636108, COSV58575739; called by muse, mutect2, varscan2
- PCDHA7 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as rs782034445, COSV65342515; called by muse, mutect2, varscan2
- PCDHA8 | c.1073C>G p.P358R | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100971087, COSV65337029; called by muse, mutect2, varscan2
- PCDHGA2 | c.1984G>A p.V662M | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as rs754195555, COSV53947328; called by muse, mutect2, varscan2
- PJVK | c.817C>A p.L273I | Missense Mutation (SNP) | VAF 88/320 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV51846333, COSV99247603; called by muse, varscan2
- PRSS12 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs780352056, COSV56606318; called by muse, mutect2, varscan2
- PRSS58 | c.428G>A p.C143Y | Missense Mutation (SNP) | VAF 79/391 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.042); catalogued as rs1250686709, COSV73488635; called by muse, mutect2, varscan2
- PTPRC | c.1358C>T p.T453M | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs771120252, COSV61408990; called by muse, mutect2, varscan2
- QSER1 | c.4501C>T p.R1501W (on ENST00000399302; = p.R1630W on NM_001076786.3) | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764240874, COSV67900587; called by muse, mutect2, varscan2
- RAI1 | c.1558G>A p.G520S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as rs147708297; called by muse, mutect2, varscan2
- SDS | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs780495084, COSV57454526; called by muse, mutect2, varscan2
- SERPINA6 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.23); catalogued as rs1329784214, COSV58584916; called by muse, mutect2, varscan2
- SGPP2 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs147179845, COSV58329083; called by muse, mutect2, varscan2
- SMYD5 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as rs116053390; called by mutect2, varscan2
- SRPX2 | c.1291T>C p.Y431H | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1271955001, COSV52167685; called by muse, mutect2, varscan2
- SYNE1 | c.10136G>A p.R3379H (on ENST00000367255 / NM_182961.4; = p.R3386H on NM_033071.3) | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs764835758, COSV54936646, COSV54980914; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TLDC2 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as rs147682253; called by muse, mutect2, varscan2
- TLL1 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as COSV50262779; called by muse, mutect2, varscan2
- TRIM42 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs201174770; called by muse, mutect2, varscan2
- TTN | c.82039A>T p.N27347Y (on ENST00000591111; = p.N19923Y on NM_003319.4) | Missense Mutation (SNP) | VAF 18/99 reads (18%) | PolyPhen benign (0.24); catalogued as COSV60060664; called by muse, mutect2, varscan2
- TTN | c.81490G>T p.D27164Y (on ENST00000591111; = p.D19740Y on NM_003319.4) | Missense Mutation (SNP) | VAF 30/157 reads (19%) | PolyPhen possibly damaging (0.575); catalogued as COSV60060710; called by muse, mutect2, varscan2
- VAT1 | c.1073T>C p.I358T | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV55896328; called by muse, mutect2, varscan2
- C2CD5 | c.2882_2883del p.L961Hfs*6 | Frame Shift Del (DEL) | VAF 45/177 reads (25%) | called by mutect2, pindel, varscan2
- IGHV1OR21-1 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTSL1 | c.2793T>C p.Y931= | Silent (SNP) | VAF 39/105 reads (37%) | catalogued as rs1375911643, COSV65892213; called by muse, mutect2, varscan2
- DDX39B | c.156C>G p.L52= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as rs1013108450, COSV58214394; called by muse, mutect2, varscan2
- ENPP6 | c.1092G>C p.R364= | Silent (SNP) | VAF 26/113 reads (23%) | catalogued as COSV57068109; called by muse, mutect2, varscan2
- HVCN1 | c.219C>T p.D73= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as rs1472137543, COSV54372150; called by muse, mutect2, varscan2
- ITGAD | c.1353G>A p.T451= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as rs374689836, COSV66757078; called by muse, mutect2, varscan2
- LRRIQ3 | c.1578T>C p.T526= | Silent (SNP) | VAF 43/175 reads (25%) | catalogued as COSV63043201; called by muse, mutect2, varscan2
- NFATC2 | c.420G>A p.P140= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1212453210, COSV65356002; called by muse, mutect2
- PCSK6 | c.1023C>T p.F341= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as rs756842286, COSV59340527; called by muse, mutect2, varscan2
- PRDM9 | c.2664C>T p.Y888= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as rs748406023, COSV57006255; called by muse, mutect2, varscan2
- RAVER1 | c.765C>T p.C255= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs751621218, COSV53345166; called by muse, mutect2, varscan2
- SLC13A2 | c.693C>T p.I231= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as rs146824818; called by muse, mutect2, varscan2
- APOE | c.*2C>T | 3'UTR (SNP) | VAF 4/20 reads (20%) | catalogued as rs760456587, COSV99375918; called by mutect2, varscan2
- DST | c.4296+4786G>A | Intron (SNP) | VAF 83/281 reads (30%) | catalogued as rs533016750, COSV99749383; ClinVar: likely benign; called by muse, mutect2, varscan2
- FUT7 | chr9:137034692 C>T | 5'Flank (SNP) | VAF 49/171 reads (29%) | catalogued as rs535490102; called by muse, mutect2, varscan2
